CCDI case PBBUYL — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/f7703b7a-112f-482c-864f-8faf16703820

Demographics
Sex at birth: male; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Brain stem; Age at diagnosis: 4.5 years (1,634 days).

Biospecimens (3 samples)
- Sample 0DI6KM: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DI6KR: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DI6KX: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
